Gene-level copy-number profile of tumor specimen HCM-CSHL-1268-C24-06A from HCMI case HCM-CSHL-1268-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 58.9 years (21,495 days).
Specimen HCM-CSHL-1268-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e26dea2b-54a1-45df-8553-0c459ba041bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1268-C24-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/ef65d94d-c9b6-454e-965e-1e5965444464

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 2,862; copy number 3: 1,093; copy number 4: 48,067; copy number 5: 620; copy number 6: 6,248; copy number 7: 6; copy number 8: 9; copy number 9: 3; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,688,463–47,704,029, 1 gene, copy number 10: LINC01738.
- chr8:28,600,469–28,755,599, 2 genes, copy number 9: EXTL3, EXTL3-AS1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
